Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3695, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3695-01A (Primary Tumor).

Diagnosis:

Right-sided hemicolectomy preparation shows tumor-free resection margins with a tubular adenoma of the ascending colon with moderate dysplasia (synonym: low-grade intraepithelial neoplasia) and includes a moderately differentiated polypous adenocarcinoma of the cecum with infiltration of the perimuscular fatty tissue and several regional lymph node metastases (G2, pT3 L1 V0 locally R0 pN2 6/33).

Source: NCI Genomic Data Commons file 39300b12-da35-4151-9948-658331239d1d (TCGA-AA-3695.2589F145-0F8D-4C7C-BDB8-A2C1843D1548.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).